Surgical pathology report (de-identified scan), TCGA case TCGA-ZT-A8OM, project TCGA-THYM (Thymoma), tissue source site  International Genomics Consortium, specimen TCGA-ZT-A8OM-01A (Primary Tumor).

[page 1 of 5]
* Final Report *

Result Type: Surg Path Final Report
Result Date:
Result Status: Auth (Verified)
Result Title: Surgical Pathology Final Report
Verified By: [REDACTED]
Encounter info:

*** Final Report ***

Final Diagnosis (Verified)

Left chest mass (with frozen section and intraoperative cytology evaluation):

Thymoma, A (epithelial-type).

Immunohistochemical stains were performed for pankeratin and CD45 and highlight mixed epithelial cells and prominent lymphocytes, consistent with the diagnosis.

Pericardium (with intraoperative cytology evaluation):

Thymoma, A (epithelial-type).

Left pericardial lymph node:

Benign lymph node with sinus histiocytosis, anthracosis, and hemosiderin deposition.

No neoplasm identified.

Special stains for GMS and AFB are negative for fungal elements and acid-fast bacilli.

Left anterior pulmonary mass:

Thymoma, A (epithelial-type).

Left pericardial phrenic mass:

Thymoma, A (epithelial-type).

Comment: A portion of this patient's specimen was submitted for flow cytometric immunophenotyping (parts A and B). Flow cytometry revealed normal non-thymic lymphocytes (see separate reports and).

This report was dictated by [REDACTED]

GENERAL COMMENT REGARDING IMMUNOPERO

Printed by: [REDACTED]
Printed on:

Page 1 of 3

CSCE ICD-O-3
Thymoma, type A NOS
8581/1
Thymoma, epithelial NOS
8585/1
Date: Mediastinum, anterior
CSCE
Chest NOS 76.1
CD 4/7/14

[page 2 of 5]
*** Final Report ***

been cleared or approved by the U.S Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing."

Signature Line

Verified on:

Operating Room Consultation (Verified)

Pericardium, mass, 2.5 x 1.9 x 0.8 cm.

ORCB with touch prep:

Favor lymphoma.

Flow sent.

Frozen Section Diagnosis (Verified)

Previous history of thymoma.

Left chest, pleural mass, 3.5 x 2.6 x 1.2 cm.

FSA with touch prep:

Favor lymphoma.

Flow sent.

Clinical Information (Verified)

Left lung mass.

Gross Description (Verified)

"FSA." All frozen section control tissue is submitted in cassette "FSA,".

"NFSA." The specimen consists of a 3.5 x 2.6 x 1.2 cm soft gray-pink fragment. On sectioning, there is a 2.1 x 1.2 x 1 cm firm tan mass. A portion of the specimen has been submitted for frozen section. Representative sections of the remaining tissue will be submitted in cassettes "A1-A2,".

"B." The specimen consists of a 2.5 x 1.9 x 0.8 cm soft gray-tan mass. "B1-B2," fragments, representative.

Printed by:

Printed on:

Page 2 of 3
(Continued)

[page 3 of 5]
*** Final Report ***

"C, Left pericardial lymph node." The specimen consists of 2 red-gray lymph nodes which measure 0.4 and 1 cm. "C," 2p, all.

"D, Left anterior pulmonary mass." The specimen consists of a 2.6 x 1.9 x 1.1 cm firm gray-tan mass. "D1-D2," fragments, representative.

"E, Left pericardial phrenic mass." The specimen consists of a 2.4 x 1.6 x 1.1 cm firm gray-tan mass. "E1-E2," fragments, representative.

NOTE: Specimen will be held for 24-hour fixation.

Received for research purposes is 1 yellow cassette labeled "

Signature Line

Completed Action List:

* Order by [REDACTED] on
* Order by [REDACTED] on
* VERIFY [REDACTED]

Printed by:
Printed on:

[REDACTED]

[page 4 of 5]
* Final Report *

Signature Line

(Electronically signed by)

Verified on:

Completed Action List:

* Order by

* Order by

* VERIFY

Printed by:

Printed on:

Page 2 of 2
(End of Report)

[page 5 of 5]
* Final Report *

Result Type: Flow Cytometry Report
Result Date:
Result Status: Auth (Verified)
Result Title: Flow Cytometry Report
Verified By: [REDACTED]
Encounter info:

* Final Report *

Interpretation (Verified)

FLOW CYTOMETRY REPORT

Specimen Type: Chest mass (corresponds to case , part A).

Findings:

The specimen consists of a predominant population of lymphocytes accounting for approximately 95% of total analyzed events. The lymphocytes are predominantly T cells with a normal immunophenotype and a prominent CD4/CD8 positive dual positive population accounting for approximately 61% of T cells. B cells account for less than 1% of lymphocytes and are quantitatively insufficient for analysis for clonality.

Interpretation:

1. Normal flow cytometric analysis for thymic lymphocytes.
2. No evidence of abnormal T cell population.
3. Insufficient B cells for analysis of clonality.

Antigens tested:

CD45, CD7, CD2, CD4, CD8, CD5, CD19, CD20, CD10, FMC-7, CD23, Kappa, Lambda, CD3, and CD56.

This report was dictated by [REDACTED] under the supervision of [REDACTED]

This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Printed by: [REDACTED]
Printed on:

Page 1 of 2
(Continued)

Source: NCI Genomic Data Commons file 981d15e1-ec86-4710-b0a6-93f29cf68b74 (TCGA-ZT-A8OM.F9F314F7-2616-489B-8484-475F78023760.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).